Somatic mutation profile of tumor specimen 0DBHZD from CCDI case PBBLGF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 16.3 years (5,949 days).
Specimen 0DBHZD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58cf6995-1db0-4da5-a0ec-27a8f97b066a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBHZ7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62c90083-5af6-4174-8aea-bb5574ee7240

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, 5'UTR 1, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1456_1457del p.L486Ifs*6 | Frame Shift Del (DEL) | VAF 82/148 reads (55%) | catalogued as rs587778832; ClinVar: pathogenic; called by mutect2, varscan2
- FGD5 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 110/281 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as rs372149660; called by muse, mutect2, varscan2
- INHBB | c.929T>C p.I310T | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs754755675; called by muse, mutect2, varscan2
- SLC26A5 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 135/381 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs150015080; called by muse, mutect2, varscan2
- TENM1 | c.7498C>T p.R2500* | Nonsense Mutation (SNP) | VAF 141/395 reads (36%) | catalogued as rs754871275; called by muse, mutect2, varscan2
- UGT8 | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs145205528; called by muse, mutect2, varscan2
- ZBED5 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 140/404 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs1213709923; called by muse, mutect2, varscan2
- BRD7 | c.592-1G>A p.X198_splice | Splice Site (SNP) | VAF 53/133 reads (40%) | called by muse, mutect2, varscan2
- CLP1 | c.196T>A p.F66I | Missense Mutation (SNP) | VAF 145/411 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ROS1 | c.5257C>T p.P1753S | Missense Mutation (SNP) | VAF 12/235 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SMARCA4 | c.3044G>T p.G1015V | Missense Mutation (SNP) | VAF 178/488 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STK33 | c.760A>C p.N254H | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- TTLL2 | c.360C>A p.D120E | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.203); called by muse, mutect2
- MMRN2 | c.1530C>T p.D510= | Silent (SNP) | VAF 114/316 reads (36%) | catalogued as COSV64400788; called by muse, mutect2, varscan2
- NOBOX | c.1659G>A p.P553= | Silent (SNP) | VAF 61/161 reads (38%) | catalogued as rs991408724, COSV56196512; ClinVar: likely benign; called by muse, mutect2, varscan2
- RLIM | c.1236T>G p.G412= | Silent (SNP) | VAF 104/340 reads (31%) | called by mutect2, varscan2
- NOL6 | c.-71_-66del | 5'UTR (DEL) | VAF 23/65 reads (35%) | called by mutect2, varscan2
